Somatic mutation profile of tumor specimen TCGA-TM-A84O-01A (aliquot TCGA-TM-A84O-01A-11D-A36O-08) from TCGA case TCGA-TM-A84O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.1 years (22,327 days).
Specimen TCGA-TM-A84O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11f7bee4-e4f5-4200-9c85-85d5e5306f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84O-10A (Blood Derived Normal), aliquot TCGA-TM-A84O-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26068561-1940-408c-98a0-64b3961627f8

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP10D | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs775497302, COSV56704962, COSV99905888; called by muse, mutect2, varscan2
- B3GALT1 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs753895355, COSV59908565, COSV59908777; called by muse, mutect2, varscan2
- CCDC198 | c.214T>C p.Y72H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as rs1229333302, COSV99371314; called by muse, mutect2, varscan2
- DLG5 | c.2930A>G p.N977S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV100967670; called by muse, mutect2, varscan2
- EDAR | c.803+1G>C p.X268_splice | Splice Site (SNP) | VAF 11/18 reads (61%) | catalogued as CS084677, COSV99303947; called by muse, mutect2, varscan2
- FAM111A | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202134817; called by muse, mutect2, varscan2
- FAM47B | c.1827G>C p.K609N | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV100264473, COSV61454053; called by muse, mutect2, varscan2
- GFPT1 | c.1961A>G p.K654R (on ENST00000357308 / NM_001244710.2; = p.K636R on NM_002056.4) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as rs751623973, COSV100622922; called by muse, mutect2, varscan2
- INO80B | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV99270654; called by muse, mutect2, varscan2
- INPP4B | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.46); catalogued as rs760400421, COSV99525601; called by muse, mutect2, varscan2
- MGA | c.8315A>C p.D2772A (on ENST00000219905 / NM_001164273.1; = p.D2563A on NM_001080541.2) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99580708; called by muse, mutect2
- MYO15A | c.3601C>T p.R1201W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs554373246, COSV52756910; called by muse, mutect2, varscan2
- OR1S2 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100224289; called by muse, mutect2, varscan2
- RIPK4 | c.2153G>A p.G718D (on ENST00000352483; = p.G670D on NM_020639.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1336835393, COSV100205184; called by muse, mutect2, varscan2
- SPDYE1 | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.187); catalogued as COSV99324044; called by muse, mutect2
- STX16 | c.919A>G p.I307V (on ENST00000371141 / NM_001001433.3; = p.I286V on NM_003763.6) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.651); catalogued as COSV100397534; called by muse, mutect2, varscan2
- TET2 | c.2056A>T p.R686* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV54396656; called by muse, mutect2, varscan2
- THUMPD2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99572294; called by muse, mutect2, varscan2
- VEZT | c.2011G>A p.G671S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99704116; called by muse, mutect2, varscan2
- VIT | c.1597C>T p.R533C (on ENST00000389975 / NM_001177969.1; = p.R548C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781780147, COSV64895682, COSV64896627; called by muse, mutect2, varscan2
- ZNF652 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100755635; called by muse, mutect2, varscan2
- ASXL1 | c.1886_1887del p.G629Afs*5 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- CIC | c.4077dup p.A1360Cfs*2 | Frame Shift Ins (INS) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- KDM1A | c.354dup p.E119Rfs*7 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.90G>A p.E30= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1441080090, COSV63463040; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1092G>A p.L364= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99404422; called by muse, mutect2, varscan2
- MROH7 | c.75G>A p.G25= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs776537724, COSV100273767; called by muse, mutect2, varscan2
- MSRB3 | c.330C>T p.H110= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs140600679; called by muse, mutect2, varscan2
- OR4C13 | c.138C>T p.T46= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs1555015698, COSV101634211; called by muse, mutect2, varscan2
- OSR2 | c.171G>A p.G57= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV52559264, COSV99882696; called by muse, mutect2, varscan2
- ZNF350 | c.1249C>T p.L417= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99702627; called by muse, mutect2, varscan2
